CCDI case PBCFCU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/480a7697-5f14-4308-b60b-0fb780e61d55

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.3 years (4,854 days).

Biospecimens (4 samples)
- Samples 0DTFRD, 0DTFRL, 0DTM9V (3 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTFRT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
